Somatic mutation profile of tumor specimen TCGA-DJ-A4V0-01A (aliquot TCGA-DJ-A4V0-01A-11D-A257-08) from TCGA case TCGA-DJ-A4V0, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 36.1 years (13,168 days).
Specimen TCGA-DJ-A4V0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77d2363c-1a6c-473c-b786-ad8782341959.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A4V0-10A (Blood Derived Normal), aliquot TCGA-DJ-A4V0-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a58c16f-a56c-46e8-86d3-d15c6a7273eb

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYA4 | c.1006C>A p.Q336K (on ENST00000531901 / NM_001301013.1; = p.Q330K on NM_004100.5) | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.185); catalogued as COSV62060453; called by muse, mutect2, varscan2
- MBIP | c.481A>G p.R161G | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59255230; called by muse, mutect2, varscan2
